Somatic mutation profile of tumor specimen ALCH-B36O-TTP1-A (aliquot ALCH-B36O-TTP1-A-1-0-D-A780-36) from ALCHEMIST case ALCH-B36O, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 55.9 years (20,402 days).
Specimen ALCH-B36O-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6102babe-041f-475e-ac05-6b2f278be323.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B36O-NB1-A (Blood Derived Normal), aliquot ALCH-B36O-NB1-A-1-0-D-A780-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fb269659-63a2-42ab-a26b-21187d6aabdf

The open-access MAF lists 206 somatic variants for this specimen: 140 protein-altering or splice-affecting, 45 silent, 21 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 124, Silent 45, Intron 12, Nonsense Mutation 9, RNA 4, 5'UTR 2, Frame Shift Ins 2, 3'UTR 2, Frame Shift Del 2, Splice Site 1, 5'Flank 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.377A>G p.Y126C | Missense Mutation (SNP) | VAF 43/282 reads (15%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1555526335, CM115636, COSV52689293, COSV52760406, COSV52970718; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ACAD10 | c.565C>T p.P189S | Missense Mutation (SNP) | VAF 32/207 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58156013; called by muse, mutect2, varscan2
- ADAMTS9 | c.5431G>T p.D1811Y | Missense Mutation (SNP) | VAF 55/422 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.334); catalogued as COSV55788486; called by muse, mutect2, varscan2
- AHI1 | c.428C>T p.P143L | Missense Mutation (SNP) | VAF 29/215 reads (13%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs192524061, COSV55631489; called by muse, mutect2, varscan2
- AL121899.2 | c.857C>A p.P286Q | Missense Mutation (SNP) | VAF 26/429 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as rs1277586780; called by muse, mutect2
- AMOT | c.1103G>A p.R368H | Missense Mutation (SNP) | VAF 36/489 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as rs370543375, COSV59065191; called by muse, mutect2
- ANKRD34C | c.349C>A p.R117S | Missense Mutation (SNP) | VAF 12/172 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.492); catalogued as COSV69854460; called by muse, mutect2
- APOA5 | c.556C>A p.R186S | Missense Mutation (SNP) | VAF 16/183 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); catalogued as rs1271898776; called by muse, mutect2
- AUTS2 | c.112G>T p.G38C | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.442); catalogued as rs752423410, COSV61391513; called by muse, mutect2, varscan2
- CCDC136 | c.2257C>T p.P753S | Missense Mutation (SNP) | VAF 40/363 reads (11%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.003); catalogued as rs267601276; called by muse, mutect2, varscan2
- CNGB1 | c.3308C>T p.A1103V | Missense Mutation (SNP) | VAF 38/767 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.053); catalogued as rs377240706; called by muse, mutect2
- CPA5 | c.1177G>A p.A393T | Missense Mutation (SNP) | VAF 53/468 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.152); catalogued as rs367924032; called by muse, mutect2, varscan2
- DNAH10 | c.8284G>A p.D2762N (on ENST00000409039; = p.D2701N on NM_207437.3) | Missense Mutation (SNP) | VAF 24/294 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1171552481; called by muse, mutect2
- FAM83H | c.580G>A p.D194N | Missense Mutation (SNP) | VAF 35/570 reads (6%) | SIFT tolerated (0.48); PolyPhen benign (0.039); catalogued as rs573911470; called by muse, mutect2
- FBN1 | c.1454G>T p.R485L | Missense Mutation (SNP) | VAF 25/468 reads (5%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.468); catalogued as rs371985966; ClinVar: uncertain significance; called by muse, mutect2
- FBXL7 | c.991G>A p.V331I | Missense Mutation (SNP) | VAF 27/335 reads (8%) | SIFT tolerated (0.29); PolyPhen benign (0.036); catalogued as rs762341690, COSV61641347; called by muse, mutect2
- FSIP2 | c.18058C>A p.L6020I | Missense Mutation (SNP) | VAF 13/145 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1444902935, COSV58087832; called by muse, mutect2
- HNF4G | c.1111C>A p.P371T (on ENST00000354370 / NM_001330561.2; = p.P418T on NM_004133.5) | Missense Mutation (SNP) | VAF 12/210 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.125); catalogued as COSV62966838; called by muse, mutect2
- IKZF1 | c.791T>C p.L264P | Missense Mutation (SNP) | VAF 84/534 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.07); catalogued as rs577045294; called by muse, mutect2, varscan2
- KCNA4 | c.1543T>G p.F515V | Missense Mutation (SNP) | VAF 31/304 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60255996; called by muse, mutect2, varscan2
- KIAA1549L | c.4763C>T p.S1588L (on ENST00000321505; = p.S1885L on NM_012194.3) | Missense Mutation (SNP) | VAF 29/517 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.307); catalogued as rs374441782; called by muse, mutect2
- LAMA1 | c.766C>T p.R256C | Missense Mutation (SNP) | VAF 40/354 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs150637419; called by muse, mutect2, varscan2
- LGALS9C | c.907C>T p.R303* | Nonsense Mutation (SNP) | VAF 46/593 reads (8%) | catalogued as rs766870750, COSV100055781; called by muse, mutect2, varscan2
- MGA | c.7307G>A p.R2436H (on ENST00000219905 / NM_001164273.1; = p.R2227H on NM_001080541.2) | Missense Mutation (SNP) | VAF 62/1158 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1054243525, COSV54949857; called by muse, mutect2
- MKRN3 | c.159G>C p.R53S | Missense Mutation (SNP) | VAF 26/352 reads (7%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as COSV58809983; called by muse, mutect2
- MS4A10 | c.361A>T p.K121* | Nonsense Mutation (SNP) | VAF 23/192 reads (12%) | catalogued as rs1382357647; called by muse, varscan2
- MUC16 | c.206C>G p.S69C | Missense Mutation (SNP) | VAF 24/176 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.788); catalogued as COSV99064185; called by muse, mutect2, varscan2
- NRAP | c.4790G>T p.R1597L (on ENST00000359988 / NM_001322945.2; = p.R1562L on NM_006175.4) | Missense Mutation (SNP) | VAF 58/962 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.426); catalogued as COSV63493154; called by muse, mutect2
- OR51S1 | c.592C>T p.P198S | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT tolerated (0.69); PolyPhen benign (0.1); catalogued as rs747194046; called by muse, mutect2
- OR5D13 | c.514G>T p.E172* | Nonsense Mutation (SNP) | VAF 21/361 reads (6%) | catalogued as COSV62335643; called by muse, mutect2
- PAH | c.886G>A p.D296N | Missense Mutation (SNP) | VAF 66/553 reads (12%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.834); catalogued as rs765934604, CM1511445; called by muse, mutect2, varscan2
- PASK | c.2885C>G p.T962S | Missense Mutation (SNP) | VAF 63/511 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1270954938; called by muse, mutect2, varscan2
- PLAC8L1 | c.160C>T p.R54W | Missense Mutation (SNP) | VAF 54/442 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs200076438, COSV61013583; called by muse, mutect2, varscan2
- PLCB4 | c.3477G>C p.Q1159H (on ENST00000278655 / NM_182797.3; = p.D1172H on NM_000933.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/470 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV53804604, COSV99593910; called by muse, mutect2
- RAB3GAP2 | c.1417G>T p.G473* | Nonsense Mutation (SNP) | VAF 84/626 reads (13%) | catalogued as rs774307849; called by muse, mutect2, varscan2
- TMEM132E | c.2737G>C p.A913P (on ENST00000321639; = p.A1003P on NM_001304438.2) | Missense Mutation (SNP) | VAF 13/152 reads (9%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.835); catalogued as rs748905055, COSV58700660; called by muse, mutect2
- TMEM38A | c.158C>T p.A53V | Missense Mutation (SNP) | VAF 36/214 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.702); catalogued as rs778995490, COSV51818316; called by muse, mutect2, varscan2
- TRIM49C | c.91G>C p.G31R | Missense Mutation (SNP) | VAF 50/424 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101442295; called by mutect2, varscan2
- TTN | c.19483A>G p.K6495E (on ENST00000591111; = p.K5568E on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/254 reads (6%) | PolyPhen benign (0.003); catalogued as COSV60387554; called by muse, mutect2
- UGT2A2 | c.557C>A p.S186* | Nonsense Mutation (SNP) | VAF 16/350 reads (5%) | catalogued as COSV54140950; called by muse, mutect2
- WNT9B | c.125C>T p.A42V | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs574292371; called by muse, mutect2, varscan2
- ZNF443 | c.1091C>T p.P364L | Missense Mutation (SNP) | VAF 40/411 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs757547901; called by muse, mutect2
- ZNF48 | c.1244G>T p.R415L | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.89); catalogued as COSV60783494; called by muse, mutect2, varscan2
- ZSCAN1 | c.487G>T p.A163S | Missense Mutation (SNP) | VAF 39/349 reads (11%) | SIFT tolerated (0.54); PolyPhen benign (0.264); catalogued as COSV56602905; called by muse, mutect2, varscan2
- A1CF | c.775G>A p.V259M | Missense Mutation (SNP) | VAF 14/258 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2
- ABCC2 | c.4081G>A p.D1361N | Missense Mutation (SNP) | VAF 36/670 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ABCF1 | c.2198G>C p.S733T (on ENST00000326195 / NM_001025091.2; = p.S695T on NM_001090.3) | Missense Mutation (SNP) | VAF 24/354 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); called by muse, mutect2
- AC055839.2 | c.105del p.A36Lfs*120 | Frame Shift Del (DEL) | VAF 17/94 reads (18%) | called by mutect2, pindel, varscan2
- ACER2 | c.728C>T p.P243L | Missense Mutation (SNP) | VAF 8/170 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- ACSM2B | c.1361G>T p.G454V | Missense Mutation (SNP) | VAF 24/550 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ADGRF2 | c.332G>T p.G111V (on ENST00000296862 / NM_001368115.2; = p.G43V on NM_153839.7) | Missense Mutation (SNP) | VAF 28/212 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by mutect2, varscan2
- ADNP | c.12dup p.P5Sfs*20 | Frame Shift Ins (INS) | VAF 45/325 reads (14%) | called by mutect2, pindel, varscan2
- AGTPBP1 | c.1814C>T p.T605I (on ENST00000357081 / NM_001330701.2; = p.T565I on NM_015239.2) | Missense Mutation (SNP) | VAF 28/277 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- ALOX5 | c.964G>T p.V322F | Missense Mutation (SNP) | VAF 22/270 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.711); called by muse, mutect2
- AMMECR1 | c.20G>T p.G7V | Missense Mutation (SNP) | VAF 14/104 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ANAPC1 | c.2320A>C p.K774Q | Missense Mutation (SNP) | VAF 10/188 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.005); called by muse, mutect2
- ANK1 | c.3388C>A p.P1130T | Missense Mutation (SNP) | VAF 12/162 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); called by muse, mutect2
- ANK3 | c.12192A>T p.L4064F | Missense Mutation (SNP) | VAF 14/202 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.235); called by muse, mutect2
- APC2 | c.3644C>A p.P1215Q | Missense Mutation (SNP) | VAF 14/111 reads (13%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.688); called by muse, mutect2, varscan2
- ARHGEF10 | c.3698T>C p.L1233P (on ENST00000398564; = p.L1208P on NM_014629.4) | Missense Mutation (SNP) | VAF 38/632 reads (6%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2
- ASAP3 | c.943G>A p.G315R | Missense Mutation (SNP) | VAF 15/218 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.065); called by muse, mutect2
- ASXL1 | c.4004G>T p.S1335I | Missense Mutation (SNP) | VAF 16/270 reads (6%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.069); called by muse, mutect2
- ATP7B | c.4091T>A p.V1364E | Missense Mutation (SNP) | VAF 31/372 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- BPIFB2 | c.979A>T p.M327L | Missense Mutation (SNP) | VAF 33/202 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- BTBD17 | c.765A>G p.I255M | Missense Mutation (SNP) | VAF 25/190 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.64); called by muse, mutect2, varscan2
- CDK8 | c.366G>T p.Q122H | Missense Mutation (SNP) | VAF 35/435 reads (8%) | SIFT tolerated (0.37); PolyPhen benign (0.02); called by muse, mutect2
- CGGBP1 | c.344A>T p.N115I | Missense Mutation (SNP) | VAF 8/184 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.193); called by muse, mutect2
- CHRM5 | c.720G>T p.E240D | Missense Mutation (SNP) | VAF 33/304 reads (11%) | SIFT tolerated (0.33); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CORO2B | c.1072C>A p.P358T | Missense Mutation (SNP) | VAF 22/194 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.666); called by muse, mutect2, varscan2
- CPB1 | c.200T>A p.V67D | Missense Mutation (SNP) | VAF 17/157 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- CYP27A1 | c.14G>A p.G5D | Missense Mutation (SNP) | VAF 62/288 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.161); called by muse, mutect2, varscan2
- DNMT3B | c.31G>T p.E11* | Nonsense Mutation (SNP) | VAF 32/602 reads (5%) | called by muse, mutect2
- E2F7 | c.1655C>T p.A552V | Missense Mutation (SNP) | VAF 110/883 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- EBF1 | c.1613C>A p.S538* | Nonsense Mutation (SNP) | VAF 38/428 reads (9%) | called by muse, mutect2
- EFHD1 | c.482G>T p.G161V | Missense Mutation (SNP) | VAF 80/373 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EPHB6 | c.1016G>A p.S339N | Missense Mutation (SNP) | VAF 78/640 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- ERICH1 | c.754G>T p.D252Y | Missense Mutation (SNP) | VAF 50/528 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.557); called by muse, mutect2
- FAM90A26 | c.93G>T p.R31S | Missense Mutation (SNP) | VAF 16/222 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.001); called by muse, mutect2
- FARSB | c.949A>G p.K317E | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.06); called by muse, mutect2
- FBN1 | c.2230G>T p.G744W | Missense Mutation (SNP) | VAF 26/558 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FLG | c.6043G>T p.D2015Y | Missense Mutation (SNP) | VAF 88/852 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- FMO3 | c.943G>T p.D315Y | Missense Mutation (SNP) | VAF 9/150 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); called by muse, mutect2
- GALR2 | c.560T>G p.M187R | Missense Mutation (SNP) | VAF 23/136 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.288); called by muse, mutect2, varscan2
- GGCX | c.1978C>T p.L660F | Missense Mutation (SNP) | VAF 88/560 reads (16%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- GINS3 | c.133G>A p.A45T | Missense Mutation (SNP) | VAF 28/346 reads (8%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); called by muse, mutect2
- GIT1 | c.926G>T p.R309L | Missense Mutation (SNP) | VAF 24/218 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- GLRB | c.1226G>T p.C409F | Missense Mutation (SNP) | VAF 22/169 reads (13%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- HMCN1 | c.11926G>T p.A3976S | Missense Mutation (SNP) | VAF 28/866 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.514); called by muse, mutect2
- HS6ST3 | c.700C>A p.H234N | Missense Mutation (SNP) | VAF 34/207 reads (16%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, mutect2
- HSD17B2 | c.664+3G>A | Splice Region (SNP) | VAF 37/625 reads (6%) | called by muse, mutect2
- IGKV1D-17 | c.43C>A p.L15I | Missense Mutation (SNP) | VAF 63/425 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.662); called by muse, varscan2
- IGSF10 | c.1219G>T p.V407L | Missense Mutation (SNP) | VAF 18/180 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ITPRID1 | c.817G>T p.V273L | Missense Mutation (SNP) | VAF 22/193 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- JAKMIP3 | c.2293G>A p.E765K | Missense Mutation (SNP) | VAF 20/316 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.23); called by muse, mutect2
- KEAP1 | c.1147T>C p.S383P | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- LACRT | c.328G>C p.V110L | Missense Mutation (SNP) | VAF 26/408 reads (6%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); called by muse, mutect2
- LRRC7 | c.2509T>A p.S837T (on ENST00000651989 / NM_001370785.2; = p.S804T on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/307 reads (8%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.012); called by muse, mutect2
- MAGEL2 | c.2268C>A p.F756L | Missense Mutation (SNP) | VAF 24/396 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.655); called by muse, mutect2
- MAP1A | c.7946G>C p.S2649T | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.011); called by muse, mutect2
- MAPK8IP1 | c.2104A>G p.T702A | Missense Mutation (SNP) | VAF 38/548 reads (7%) | SIFT tolerated (0.64); PolyPhen benign (0.057); called by muse, mutect2
- MMP2 | c.1109A>G p.D370G | Missense Mutation (SNP) | VAF 25/433 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.218); called by muse, mutect2
- MTMR6 | c.841C>A p.L281I | Missense Mutation (SNP) | VAF 24/211 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, varscan2
- MYLK | c.3187A>G p.S1063G | Missense Mutation (SNP) | VAF 77/719 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); called by mutect2, varscan2
- NEDD1 | c.1691C>T p.A564V | Missense Mutation (SNP) | VAF 54/355 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- NEK1 | c.913G>A p.A305T | Missense Mutation (SNP) | VAF 50/384 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.743); called by muse, mutect2, varscan2
- NFASC | c.325C>G p.P109A (on ENST00000339876 / NM_001378329.1; = p.P103A on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/342 reads (10%) | SIFT tolerated (0.98); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- NOS1 | c.242T>C p.L81P | Missense Mutation (SNP) | VAF 30/191 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR2L2 | c.879dup p.K294Qfs*31 | Frame Shift Ins (INS) | VAF 22/180 reads (12%) | called by mutect2, varscan2
- OR51A4 | c.838G>T p.V280F | Missense Mutation (SNP) | VAF 32/753 reads (4%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.77); called by muse, mutect2
- OR51G2 | c.745C>A p.H249N | Missense Mutation (SNP) | VAF 12/302 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- OTOA | c.1624G>T p.G542* (on ENST00000286149; = p.G528* on NM_144672.4) | Nonsense Mutation (SNP) | VAF 38/550 reads (7%) | called by muse, mutect2
- OTOG | c.7562C>A p.P2521Q | Missense Mutation (SNP) | VAF 50/373 reads (13%) | SIFT tolerated (0.64); PolyPhen benign (0.389); called by muse, mutect2, varscan2
- PAN3 | c.1735A>C p.M579L | Missense Mutation (SNP) | VAF 46/479 reads (10%) | SIFT tolerated (0.43); PolyPhen benign (0.005); called by muse, mutect2
- PCDHB5 | c.2378G>T p.G793V | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.048); called by muse, varscan2
- PLSCR2 | c.233C>T p.P78L (on ENST00000497985 / NM_001199978.1; = p.P5L on NM_020359.2) | Missense Mutation (SNP) | VAF 83/723 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- RAD51D | c.164G>T p.R55L | Missense Mutation (SNP) | VAF 40/684 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.639); called by muse, mutect2
- RALGAPA2 | c.4667A>T p.Q1556L | Missense Mutation (SNP) | VAF 16/282 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.024); called by muse, mutect2
- RASGEF1C | c.289G>A p.V97M | Missense Mutation (SNP) | VAF 66/550 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.247); called by muse, mutect2, varscan2
- RFPL4A | c.836G>T p.S279I | Missense Mutation (SNP) | VAF 50/508 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- RIMBP3 | c.1820C>T p.A607V | Missense Mutation (SNP) | VAF 35/753 reads (5%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.46); called by muse, mutect2
- ROR2 | c.1631C>G p.T544S | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.019); called by muse, mutect2
- RPGRIP1L | c.29G>T p.G10V | Missense Mutation (SNP) | VAF 36/740 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, mutect2
- SBNO2 | c.4050G>C p.Q1350H | Missense Mutation (SNP) | VAF 29/185 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- SERPINB10 | c.560T>A p.L187Q | Missense Mutation (SNP) | VAF 48/486 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2
- SLC17A4 | c.983G>C p.R328T | Missense Mutation (SNP) | VAF 7/98 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.014); called by muse, mutect2
- SLC25A36 | c.308C>T p.S103L | Missense Mutation (SNP) | VAF 30/187 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, varscan2
- STK11 | c.205_206del p.S69Gfs*93 | Frame Shift Del (DEL) | VAF 37/293 reads (13%) | called by mutect2, pindel, varscan2
- TET1 | c.2669A>T p.Q890L | Missense Mutation (SNP) | VAF 16/135 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TNC | c.5555A>G p.Y1852C | Missense Mutation (SNP) | VAF 45/375 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- TOX2 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 30/386 reads (8%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.046); called by muse, mutect2
- TP73 | c.1012C>G p.P338A | Missense Mutation (SNP) | VAF 20/228 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.214); called by muse, mutect2
- TRBV4-1 | c.85C>A p.H29N | Missense Mutation (SNP) | VAF 31/178 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- UBA2 | c.484C>T p.H162Y | Missense Mutation (SNP) | VAF 50/273 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- USP28 | c.2521G>T p.V841L | Missense Mutation (SNP) | VAF 38/345 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- WARS1 | c.805T>A p.F269I | Missense Mutation (SNP) | VAF 16/156 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- WWC2 | c.2563-1G>C p.X855_splice | Splice Site (SNP) | VAF 62/355 reads (17%) | called by muse, varscan2
- ZFYVE26 | c.2029G>T p.G677* | Nonsense Mutation (SNP) | VAF 10/212 reads (5%) | called by muse, mutect2
- ZNF239 | c.279A>T p.R93S | Missense Mutation (SNP) | VAF 14/353 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.001); called by muse, mutect2
- ZNF572 | c.543G>A p.M181I | Missense Mutation (SNP) | VAF 17/353 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- ZNF786 | c.724T>A p.C242S | Missense Mutation (SNP) | VAF 29/323 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.726); called by muse, mutect2
- A2M | c.1461G>A p.L487= | Silent (SNP) | VAF 20/266 reads (8%) | called by muse, mutect2
- ALG9 | c.693A>T p.A231= | Silent (SNP) | VAF 56/746 reads (8%) | catalogued as COSV67645341; called by muse, mutect2
- ANAPC1 | c.597T>G p.P199= | Silent (SNP) | VAF 22/392 reads (6%) | called by muse, mutect2
- ANKRD30A | c.3447C>T p.T1149= (on ENST00000611781; = p.T1093= on NM_052997.2) | Silent (SNP) | VAF 15/338 reads (4%) | catalogued as COSV64608971, COSV64621245; called by muse, mutect2
- AP5Z1 | c.1668G>T p.V556= | Silent (SNP) | VAF 9/234 reads (4%) | called by muse, mutect2
- ASXL3 | c.1230C>T p.S410= | Silent (SNP) | VAF 56/630 reads (9%) | called by muse, mutect2
- C10orf90 | c.1089T>C p.S363= | Silent (SNP) | VAF 12/221 reads (5%) | catalogued as COSV52956519; called by muse, mutect2
- CHRM2 | c.984C>T p.G328= | Silent (SNP) | VAF 14/156 reads (9%) | called by muse, mutect2
- CNGB3 | c.1989C>A p.A663= | Silent (SNP) | VAF 25/489 reads (5%) | called by muse, mutect2
- COPG1 | c.858C>A p.A286= | Silent (SNP) | VAF 14/228 reads (6%) | called by muse, mutect2
- CPZ | c.1314G>T p.L438= (on ENST00000360986 / NM_001014447.3; = p.L427= on NM_003652.3) | Silent (SNP) | VAF 13/184 reads (7%) | called by muse, mutect2
- DOCK9 | c.1302G>T p.A434= (on ENST00000376460 / NM_001366676.2; = p.A435= on NM_015296.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 89/809 reads (11%) | catalogued as rs1265110527, COSV59637131; called by muse, mutect2, varscan2
- FAM181B | c.1215C>T p.S405= | Silent (SNP) | VAF 18/261 reads (7%) | called by muse, mutect2
- FAM181B | c.114C>T p.F38= | Silent (SNP) | VAF 43/456 reads (9%) | catalogued as rs773906493; called by muse, mutect2
- FBH1 | c.291A>G p.A97= (on ENST00000362091 / NM_178150.3; = p.A148= on NM_032807.4) | Silent (SNP) | VAF 24/361 reads (7%) | called by muse, mutect2
- FREM3 | c.4551C>T p.G1517= | Silent (SNP) | VAF 40/331 reads (12%) | catalogued as rs554812138; called by muse, mutect2, varscan2
- HCN1 | c.1998G>T p.P666= | Silent (SNP) | VAF 165/964 reads (17%) | catalogued as rs758849997, COSV57528031; called by muse, mutect2, varscan2
- HECTD4 | c.807G>T p.G269= | Silent (SNP) | VAF 54/345 reads (16%) | called by muse, mutect2, varscan2
- HTR1D | c.714C>A p.R238= | Silent (SNP) | VAF 55/410 reads (13%) | catalogued as rs1447223605; called by muse, mutect2, varscan2
- IQGAP3 | c.996C>T p.D332= | Silent (SNP) | VAF 32/578 reads (6%) | called by muse, mutect2
- LUZP2 | c.1017A>G p.A339= | Silent (SNP) | VAF 40/345 reads (12%) | called by muse, mutect2, varscan2
- MAGEA11 | c.747G>A p.L249= | Silent (SNP) | VAF 15/136 reads (11%) | called by muse, mutect2, varscan2
- MARK2 | c.1350A>T p.T450= (on ENST00000402010 / NM_001039469.2; = p.T449= on NM_004954.5) | Silent (SNP) | VAF 45/344 reads (13%) | called by muse, mutect2, varscan2
- MICAL3 | c.1785C>A p.I595= | Silent (SNP) | VAF 16/290 reads (6%) | called by muse, mutect2
- MINDY4B | c.660C>T p.D220= | Silent (SNP) | VAF 24/221 reads (11%) | catalogued as rs1302985193; called by muse, mutect2, varscan2
- N4BP2 | c.3573G>A p.Q1191= | Silent (SNP) | VAF 21/247 reads (9%) | called by muse, mutect2
- NPTXR | c.351G>A p.P117= | Silent (SNP) | VAF 6/55 reads (11%) | catalogued as rs1202690617, COSV60728464; called by muse, mutect2, varscan2
- NTRK3 | c.381C>A p.P127= | Silent (SNP) | VAF 32/591 reads (5%) | called by muse, mutect2
- OR51G2 | c.744C>A p.S248= | Silent (SNP) | VAF 14/304 reads (5%) | called by muse, mutect2
- OR52I2 | c.249C>A p.S83= | Silent (SNP) | VAF 50/824 reads (6%) | called by muse, mutect2
- PARP12 | c.1836G>A p.T612= | Silent (SNP) | VAF 37/340 reads (11%) | catalogued as rs1313383363; called by muse, mutect2, varscan2
- PDZRN3 | c.1770C>G p.G590= | Silent (SNP) | VAF 64/511 reads (13%) | catalogued as rs146622509; called by muse, mutect2, varscan2
- PDZRN3 | c.456C>T p.H152= | Silent (SNP) | VAF 25/124 reads (20%) | catalogued as rs1036313584; called by muse, mutect2, varscan2
- PTPRN2 | c.1992C>T p.A664= | Silent (SNP) | VAF 48/493 reads (10%) | catalogued as rs186491359, COSV67051618; called by muse, mutect2, varscan2
- RASGRF1 | c.3003C>T p.A1001= | Silent (SNP) | VAF 13/454 reads (3%) | called by muse, mutect2
- RASSF4 | c.16C>T p.L6= | Silent (SNP) | VAF 10/262 reads (4%) | called by muse, mutect2
- RNF213 | c.5172C>T p.A1724= | Silent (SNP) | VAF 24/356 reads (7%) | catalogued as rs540004284; called by muse, mutect2
- SH2D5 | c.598C>A p.R200= (on ENST00000444387 / NM_001103161.2; = p.R116= on NM_001103160.2) | Silent (SNP) | VAF 11/156 reads (7%) | called by muse, mutect2
- SHISA9 | c.960G>A p.G320= | Silent (SNP) | VAF 38/293 reads (13%) | called by muse, mutect2, varscan2
- SRMS | c.879G>C p.S293= | Silent (SNP) | VAF 42/249 reads (17%) | catalogued as COSV99420529; called by muse, mutect2, varscan2
- TESK1 | c.156G>T p.A52= | Silent (SNP) | VAF 20/259 reads (8%) | catalogued as rs777802624; called by muse, mutect2
- TG | c.8139C>T p.A2713= | Silent (SNP) | VAF 22/472 reads (5%) | catalogued as rs768913752, COSV99600356; called by muse, mutect2
- TRAIP | c.132G>T p.R44= | Silent (SNP) | VAF 50/393 reads (13%) | called by muse, mutect2, varscan2
- URB1 | c.4476T>G p.S1492= | Silent (SNP) | VAF 47/815 reads (6%) | called by muse, mutect2
- ZFYVE26 | c.4801C>T p.L1601= | Silent (SNP) | VAF 104/940 reads (11%) | catalogued as rs139735970; called by muse, mutect2, varscan2
- AC245047.1 | n.149dup | RNA (INS) | VAF 24/163 reads (15%) | catalogued as rs1569445547; called by mutect2, pindel, varscan2
- AHI1 | c.135+416G>T | Intron (SNP) | VAF 10/256 reads (4%) | called by muse, mutect2
- ARMCX4 | c.1039-3568G>T | Intron (SNP) | VAF 16/88 reads (18%) | called by muse, mutect2, varscan2
- COL4A3 | c.1504+15C>T | Intron (SNP) | VAF 73/506 reads (14%) | called by muse, mutect2, varscan2
- DNAH10 | c.1816-2628A>T | Intron (SNP) | VAF 18/140 reads (13%) | called by muse, mutect2, varscan2
- DNAI1 | c.1719-41A>G | Intron (SNP) | VAF 32/301 reads (11%) | called by muse, mutect2, varscan2
- IGFN1 | c.1242-3225T>G | Intron (SNP) | VAF 24/714 reads (3%) | called by muse, mutect2
- LILRA2 | c.1255+1485C>A | Intron (SNP) | VAF 30/284 reads (11%) | called by muse, mutect2, varscan2
- MARCHF1 | c.-322-86024C>G | Intron (SNP) | VAF 44/702 reads (6%) | catalogued as COSV72283448; called by muse, mutect2
- MOCS1 | chr6:39934521 C>A | 5'Flank (SNP) | VAF 8/95 reads (8%) | catalogued as rs1285113027; called by muse, mutect2
- MS4A1 | c.-24A>G | 5'UTR (SNP) | VAF 40/480 reads (8%) | called by muse, mutect2
- MSLN | c.1807+37C>T | Intron (SNP) | VAF 32/149 reads (21%) | catalogued as rs1326788828; called by muse, mutect2, varscan2
- MYH16 | n.2932C>A | RNA (SNP) | VAF 12/69 reads (17%) | called by muse, mutect2, varscan2
- PLA2G15 | c.128-714G>T | Intron (SNP) | VAF 6/65 reads (9%) | called by muse, mutect2
- RAB5A | c.*421T>C | 3'UTR (SNP) | VAF 8/90 reads (9%) | called by muse, mutect2
- RABGAP1L | c.2212-11384T>G | Intron (SNP) | VAF 20/308 reads (6%) | called by muse, mutect2
- SPEF2 | c.4448-3527C>G | Intron (SNP) | VAF 12/135 reads (9%) | called by muse, mutect2
- SSPOP | n.10521G>T | RNA (SNP) | VAF 48/401 reads (12%) | called by muse, mutect2, varscan2
- SSPOP | n.10522G>T | RNA (SNP) | VAF 47/402 reads (12%) | called by muse, mutect2, varscan2
- TAF10 | c.*264del | 3'UTR (DEL) | VAF 33/275 reads (12%) | called by mutect2, pindel, varscan2
- ZNF436 | c.-238C>G | 5'UTR (SNP) | VAF 13/137 reads (9%) | called by muse, mutect2
